Somatic mutation profile of tumor specimen TCGA-BB-4224-01A (aliquot TCGA-BB-4224-01A-01D-1434-08) from TCGA case TCGA-BB-4224, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 52.3 years (19,119 days).
Specimen TCGA-BB-4224-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13895497-c60c-4f53-a211-434b051e9318.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BB-4224-10A (Blood Derived Normal), aliquot TCGA-BB-4224-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/11803bab-e233-4e94-b303-064c0336c447

The open-access MAF lists 80 somatic variants for this specimen: 62 protein-altering or splice-affecting, 16 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 16, Nonsense Mutation 5, Frame Shift Del 3, Splice Site 1, Intron 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1420C>T p.R474* | Nonsense Mutation (SNP) | VAF 78/192 reads (41%) | catalogued as rs1553631860, CM150338, COSV62729563; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 20/87 reads (23%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10979C>G p.S3660* | Nonsense Mutation (SNP) | VAF 87/831 reads (10%) | catalogued as COSV101446925; called by muse, mutect2, varscan2
- ACBD6 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 35/46 reads (76%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.559); catalogued as COSV100852465; called by muse, mutect2, varscan2
- AGO2 | c.1650G>C p.K550N | Missense Mutation (SNP) | VAF 45/172 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99595630; called by muse, mutect2, varscan2
- AKAP12 | c.2209C>A p.P737T | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.045); catalogued as rs781225876, COSV99483074; called by muse, mutect2, varscan2
- AKAP13 | c.7579C>T p.H2527Y (on ENST00000394518 / NM_007200.5; = p.H2531Y on NM_006738.6) | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV100773668; called by muse, mutect2, varscan2
- AMBRA1 | c.3651G>T p.E1217D (on ENST00000458649 / NM_001367468.1; = p.E1127D on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/304 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as COSV54059154; called by muse, mutect2
- AP2B1 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99251165; called by muse, mutect2, varscan2
- ATAD5 | c.479G>A p.R160H | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs375111527; called by muse, mutect2, varscan2
- ATP8B4 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1376889811, COSV52721344; called by muse, mutect2, varscan2
- CACNA1I | c.412G>T p.G138W | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100360035, COSV60801760, COSV60803716; called by mutect2, varscan2
- CEP135 | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV99954366; called by muse, mutect2, varscan2
- COL6A6 | c.3776A>G p.E1259G | Missense Mutation (SNP) | VAF 55/264 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); catalogued as COSV100650187; called by muse, mutect2, varscan2
- CREB3L2 | c.78C>G p.D26E | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100381851; called by muse, mutect2, varscan2
- CTNNA3 | c.1495G>A p.D499N | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.339); catalogued as COSV101048725; called by muse, mutect2, varscan2
- DNAH5 | c.6971C>A p.T2324K | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54246825; called by muse, mutect2, varscan2
- DYNC1H1 | c.6937G>A p.E2313K | Missense Mutation (SNP) | VAF 66/183 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100794797; called by muse, mutect2, varscan2
- DYNC1H1 | c.10951C>T p.R3651C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV100794798; called by muse, mutect2, varscan2
- ESRRA | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.175); catalogued as COSV50005534; called by muse, mutect2, varscan2
- FAM151A | c.639C>A p.F213L | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100156865, COSV56362967; called by muse, mutect2, varscan2
- GPATCH3 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.359); catalogued as COSV100658772; called by muse, mutect2, varscan2
- H2BC12 | c.170C>G p.S57C | Missense Mutation (SNP) | VAF 81/554 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.968); catalogued as COSV100804654; called by muse, mutect2, varscan2
- IGHMBP2 | c.1178G>T p.R393I | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as COSV99662023; called by muse, mutect2, varscan2
- IL37 | c.367G>C p.D123H | Missense Mutation (SNP) | VAF 50/202 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV99636161; called by muse, mutect2, varscan2
- INSM1 | c.348C>G p.F116L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs1295959597, COSV100044669; called by muse, mutect2, varscan2
- IRAK4 | c.1174G>T p.E392* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV101471816; called by muse, mutect2, varscan2
- LRP2 | c.6691G>A p.E2231K | Missense Mutation (SNP) | VAF 72/265 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.424); catalogued as COSV99788059; called by muse, mutect2, varscan2
- LRP4 | c.3472C>T p.R1158W | Missense Mutation (SNP) | VAF 68/386 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886048351, COSV66138483; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LUC7L2 | c.133C>T p.P45S | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99692998; called by muse, mutect2, varscan2
- MAPK4 | c.495G>C p.K165N | Missense Mutation (SNP) | VAF 74/109 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101245400; called by muse, mutect2, varscan2
- MUC16 | c.6436C>A p.L2146I | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV101199598, COSV67464082, COSV67478986; called by muse, mutect2, varscan2
- MYO10 | c.3748G>A p.E1250K | Missense Mutation (SNP) | VAF 66/303 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.944); catalogued as COSV57031226, COSV99945231; called by muse, mutect2, varscan2
- MYORG | c.1253G>A p.R418Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs1487181829, COSV52627518; called by muse, varscan2
- NANS | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 24/158 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV99271217; called by muse, mutect2, varscan2
- NAPRT | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as rs1352396176, COSV99434707; called by muse, mutect2
- NDC1 | c.736A>G p.M246V | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs140272518; called by muse, mutect2, varscan2
- NDNF | c.841T>G p.Y281D | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV101113154; called by muse, mutect2, varscan2
- NRXN1 | c.3400C>G p.Q1134E | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV100454707, COSV58466135; called by muse, mutect2, varscan2
- OR13C4 | c.619C>A p.L207I | Missense Mutation (SNP) | VAF 67/207 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.411); catalogued as COSV99470132; called by muse, mutect2, varscan2
- OR5V1 | c.519G>T p.Q173H | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101011250; called by muse, mutect2, varscan2
- PAGE2 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as rs867478330, COSV100892295; called by muse, mutect2, varscan2
- PCNX2 | c.3603G>C p.L1201F | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99267189; called by muse, mutect2, varscan2
- PKHD1L1 | c.4961G>A p.R1654Q | Missense Mutation (SNP) | VAF 192/733 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.288); catalogued as rs373094487, COSV65747646; called by muse, mutect2, varscan2
- RPRD2 | c.228T>A p.N76K | Missense Mutation (SNP) | VAF 89/322 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); catalogued as COSV100954714, COSV64816830; called by muse, mutect2, varscan2
- RPRD2 | c.229C>G p.L77V | Missense Mutation (SNP) | VAF 90/323 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.752); catalogued as COSV64816848; called by muse, mutect2, varscan2
- SEMA3A | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99546317; called by muse, mutect2, varscan2
- SFMBT2 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752198642, COSV62813928; called by muse, mutect2, varscan2
- SIRPG | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 37/204 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1281567353, COSV53805960; called by muse, mutect2, varscan2
- SQOR | c.1133C>G p.S378* | Nonsense Mutation (SNP) | VAF 61/328 reads (19%) | catalogued as COSV99525733; called by muse, mutect2, varscan2
- TDO2 | c.141+2T>C p.X47_splice | Splice Site (SNP) | VAF 24/58 reads (41%) | catalogued as COSV101539737; called by muse, varscan2
- TP53 | c.656_657del p.P219Lfs*2 | Frame Shift Del (DEL) | VAF 22/49 reads (45%) | catalogued as COSV52757494, COSV52926388; called by mutect2, pindel, varscan2
- TRPM6 | c.4318C>T p.L1440F | Missense Mutation (SNP) | VAF 46/267 reads (17%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.054); catalogued as rs1229187260, COSV100666241, COSV62517359; called by muse, mutect2, varscan2
- UNK | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1350207405, COSV53147461; called by muse, mutect2, varscan2
- WWP1 | c.2072T>A p.L691H | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as COSV99616274; called by muse, mutect2, varscan2
- ZMYND11 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 59/201 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.313); catalogued as COSV100556219; called by muse, mutect2, varscan2
- ZNF169 | c.982C>T p.R328C | Missense Mutation (SNP) | VAF 48/334 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100566217; called by muse, varscan2
- ZNF510 | c.1162A>T p.T388S | Missense Mutation (SNP) | VAF 86/560 reads (15%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV99793833; called by muse, mutect2, varscan2
- ZNF804B | c.3002C>T p.T1001M | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.176); catalogued as rs375356215; called by muse, mutect2, varscan2
- DDX52 | c.156G>C p.K52N | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- RSF1 | c.3006del p.K1002Nfs*18 | Frame Shift Del (DEL) | VAF 25/110 reads (23%) | called by mutect2, pindel, varscan2
- YTHDC1 | c.1207_1208del p.V403Qfs*34 (on ENST00000344157 / NM_001031732.4; = p.V385Qfs*34 on NM_133370.4) | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | called by mutect2, pindel, varscan2
- ADAMTS18 | c.234C>T p.H78= | Silent (SNP) | VAF 110/601 reads (18%) | catalogued as rs369294701; called by muse, mutect2, varscan2
- ARHGAP17 | c.190A>C p.R64= | Silent (SNP) | VAF 40/83 reads (48%) | catalogued as COSV99253328; called by muse, mutect2, varscan2
- BSCL2 | c.1126C>T p.L376= | Silent (SNP) | VAF 24/115 reads (21%) | catalogued as COSV99628160; called by muse, mutect2, varscan2
- C12orf60 | c.360G>A p.T120= | Silent (SNP) | VAF 47/397 reads (12%) | catalogued as rs575360384, COSV57453796; called by muse, mutect2, varscan2
- C19orf57 | c.546G>A p.A182= | Silent (SNP) | VAF 55/171 reads (32%) | catalogued as rs760177608, COSV100694688; called by muse, mutect2, varscan2
- CUX2 | c.948C>T p.D316= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs756898105, COSV55636804; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.910C>T p.L304= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV50052261, COSV99143637; called by muse, mutect2, varscan2
- ENTPD8 | c.51G>A p.S17= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs765558030, COSV58160870; called by muse, mutect2, varscan2
- MRFAP1L1 | c.72C>T p.F24= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV57922898; called by muse, mutect2, varscan2
- PCDH17 | c.1680C>T p.P560= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV100931578; called by muse, mutect2, varscan2
- PGGHG | c.1753C>T p.L585= | Silent (SNP) | VAF 41/152 reads (27%) | catalogued as rs944890113, COSV101164420; called by muse, mutect2, varscan2
- REXO2 | c.303C>T p.H101= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs151260750; called by muse, mutect2, varscan2
- SRCAP | c.5577C>T p.S1859= | Silent (SNP) | VAF 139/305 reads (46%) | catalogued as COSV99349983; called by muse, mutect2, varscan2
- TAS2R50 | c.618C>G p.L206= | Silent (SNP) | VAF 60/440 reads (14%) | catalogued as rs760258562, COSV101114661; called by muse, mutect2, varscan2
- TNFRSF21 | c.243C>A p.T81= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as COSV99729498; called by muse, mutect2, varscan2
- WSCD2 | c.1299C>T p.Y433= | Silent (SNP) | VAF 34/170 reads (20%) | catalogued as COSV54587190; called by muse, mutect2, varscan2
- HLA-DRB9 | n.330C>A | RNA (SNP) | VAF 89/156 reads (57%) | called by muse, mutect2, varscan2
- RICTOR | c.4136+309C>T | Intron (SNP) | VAF 29/143 reads (20%) | catalogued as rs145088420, COSV99704819; called by muse, mutect2, varscan2
